Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A44P, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A44P-01A (Primary Tumor).

Procurement Date: Laterality: Malignant melanoma with superficial ulceration. Breslow's depth is 6 mm.

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, trunk

Tumor size: 1.2 x 0 x 1.5 cm

Tumor features: Ulcerated

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Breslow's depth is 6 mm.

1CD-03
melanoma, NOS
8720/3
Site: skin, trunk
c44.5
8/31/12
RO

Source: NCI Genomic Data Commons file 75a83ece-783a-44f8-b658-f43a4a8d20de (TCGA-EB-A44P.820D5744-25BF-46E9-8832-57953EF4ECC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).